Somatic mutation profile of tumor specimen MP2PRT-PATFCN-TMP1-A (aliquot MP2PRT-PATFCN-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFCN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 20.7 years (7,549 days).
Specimen MP2PRT-PATFCN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c90cb2-8682-48fa-a693-1afbcd6adfc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFCN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFCN-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/454d93c6-9392-45f5-932b-595b3b68ec16

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ART5 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs750669805; called by muse, mutect2, varscan2
- GPR25 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 128/638 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs941682167, COSV58499075; called by muse, mutect2, varscan2
- GRAMD4 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs971965278, COSV63029443; called by muse, mutect2, varscan2
- ITGA7 | c.2788G>A p.G930R (on ENST00000555728; = p.G886R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.198); catalogued as rs764017834, COSV99169353; called by muse, mutect2, varscan2
- MYT1L | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); catalogued as rs774451946, COSV67707093; called by muse, mutect2
- PAPSS2 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 51/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1406833604, COSV63265213; called by muse, mutect2, varscan2
- PLS3 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.493); catalogued as rs1556641663; called by muse, mutect2, varscan2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- ROBO2 | c.2499C>T p.I833= | Splice Region (SNP) | VAF 16/234 reads (7%) | catalogued as rs200415597; called by muse, mutect2
- DUSP26 | c.25_44delinsCCGAAGGGGG p.A9Pfs*115 | Frame Shift Del (DEL) | VAF 62/316 reads (20%) | called by pindel, varscan2*
- FLNA | c.4124A>T p.K1375M | Missense Mutation (SNP) | VAF 91/697 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MAGOHB | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- NCAN | c.3187G>T p.D1063Y | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.18109G>A p.A6037T | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCNM1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 93/476 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WNK1 | c.43T>A p.S15T | Missense Mutation (SNP) | VAF 89/439 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDYL2 | c.1167G>A p.T389= | Silent (SNP) | VAF 125/457 reads (27%) | catalogued as rs1295110251, COSV73653938; called by muse, mutect2, varscan2
- DSCAML1 | c.1323C>T p.S441= (on ENST00000321322; = p.S381= on NM_020693.4) | Silent (SNP) | VAF 40/542 reads (7%) | catalogued as rs922806597, COSV58398887; called by muse, mutect2
- KNDC1 | c.2484G>A p.P828= | Silent (SNP) | VAF 194/1043 reads (19%) | catalogued as rs551786373; called by muse, mutect2, varscan2
- NFATC4 | c.1341C>T p.G447= | Silent (SNP) | VAF 22/474 reads (5%) | catalogued as rs564143493, COSV99144344; called by muse, mutect2
- PELP1 | c.2697A>G p.E899= | Silent (SNP) | VAF 92/475 reads (19%) | catalogued as rs200508582, COSV52585958; called by muse, mutect2, varscan2
